Somatic mutation profile of tumor specimen TCGA-SX-A71S-01A (aliquot TCGA-SX-A71S-01A-11D-A33Q-10) from TCGA case TCGA-SX-A71S, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 66.3 years (24,211 days).
Specimen TCGA-SX-A71S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5587c2de-95b1-4685-a600-eef3acb0fcc6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SX-A71S-10A (Blood Derived Normal), aliquot TCGA-SX-A71S-10A-01D-A33Q-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26ad45e2-0c87-430f-9e76-b5c0b2eadc7e

The open-access MAF lists 141 somatic variants for this specimen: 101 protein-altering or splice-affecting, 36 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 36, Frame Shift Del 8, Frame Shift Ins 7, Nonsense Mutation 6, 5'UTR 2, Intron 1, Splice Region 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MET | c.3689A>G p.Y1230C | Missense Mutation (SNP) | VAF 82/124 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913246, CM970947, COSV59257466, COSV59260641; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRG6 | c.465T>A p.N155K | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99746221; called by muse, mutect2, varscan2
- ALDH2 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.78); PolyPhen benign (0.006); catalogued as rs1390568209, COSV99922775; called by muse, mutect2, varscan2
- APIP | c.153G>T p.K51N | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99551473; called by muse, mutect2, varscan2
- BACH1 | c.2081G>A p.R694Q | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs377002114; called by muse, mutect2, varscan2
- BPTF | c.4666A>G p.R1556G | Missense Mutation (SNP) | VAF 50/177 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV100074343; called by muse, mutect2, varscan2
- CALML4 | c.320T>G p.L107R | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100682813; called by muse, mutect2, varscan2
- CASP8 | c.1285C>A p.L429M (on ENST00000432109 / NM_033355.3; = p.L446M on NM_001228.4) | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.946); catalogued as COSV51847001; called by muse, mutect2, varscan2
- CCR9 | c.339G>T p.K113N (on ENST00000357632 / NM_031200.3; = p.K101N on NM_006641.4) | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as COSV62940724; called by muse, mutect2, varscan2
- CD180 | c.1595T>C p.L532P | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99842137; called by muse, mutect2, varscan2
- CEP250 | c.5729G>A p.C1910Y | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.748); catalogued as COSV100698792; called by muse, mutect2, varscan2
- CHAF1A | c.2366A>T p.D789V | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV100010936; called by muse, mutect2, varscan2
- CMTR1 | c.2431G>T p.D811Y | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100982877; called by muse, mutect2, varscan2
- CNTNAP3 | c.1694C>T p.S565L | Missense Mutation (SNP) | VAF 196/485 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as rs781066365, COSV52666846; called by muse, mutect2, varscan2
- COL18A1 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.096); catalogued as COSV62700505; called by muse, mutect2, varscan2
- COL20A1 | c.893C>T p.T298I | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT tolerated (0.54); PolyPhen benign (0.25); catalogued as rs751802659, COSV100490074; called by muse, mutect2, varscan2
- COPS9 | c.90G>T p.M30I (on ENST00000607357 / NM_001163424.2; = p.M61I on NM_138336.1) | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.584); catalogued as COSV100216951; called by muse, mutect2, varscan2
- CPNE6 | c.1658C>A p.P553H | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV99393200; called by muse, mutect2, varscan2
- DNAJA3 | c.1423A>T p.K475* | Nonsense Mutation (SNP) | VAF 38/83 reads (46%) | catalogued as rs769335546, COSV99276505; called by muse, mutect2, varscan2
- DSCAM | c.2609C>T p.S870F | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs895730848, COSV101259430; called by muse, mutect2, varscan2
- DYNC1H1 | c.13145C>G p.T4382S | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV100794623; called by muse, mutect2, varscan2
- FLII | c.167A>G p.Q56R | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.042); catalogued as COSV100493529; called by muse, mutect2, varscan2
- GBA2 | c.685C>T p.H229Y | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100803317; called by muse, mutect2, varscan2
- GOLGA4 | c.3618T>A p.F1206L | Missense Mutation (SNP) | VAF 93/220 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV100728719; called by muse, mutect2, varscan2
- GOLGB1 | c.5626C>A p.Q1876K | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.794); catalogued as COSV100510443; called by muse, mutect2, varscan2
- GPM6A | c.690C>A p.H230Q | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.995); catalogued as COSV99703043; called by muse, mutect2, varscan2
- GPRC6A | c.1100T>A p.V367D | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.522); catalogued as COSV100114126; called by muse, mutect2, varscan2
- GSDMA | c.147G>T p.W49C | Missense Mutation (SNP) | VAF 64/97 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100053559; called by muse, mutect2, varscan2
- HAUS6 | c.932T>A p.L311* | Nonsense Mutation (SNP) | VAF 64/169 reads (38%) | catalogued as COSV100997776; called by muse, mutect2, varscan2
- HDGF | c.673A>T p.T225S | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); catalogued as COSV100625647; called by muse, mutect2, varscan2
- HERC2 | c.6802T>C p.F2268L | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV99871661; called by muse, mutect2, varscan2
- HEY1 | c.390C>G p.C130W | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100559180; called by muse, mutect2, varscan2
- IBA57 | c.400G>A p.G134S | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.029); catalogued as rs752194403, COSV100812759; called by muse, mutect2, varscan2
- KCTD12 | c.793C>G p.R265G | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as rs1056365517, COSV100499664; called by muse, mutect2, varscan2
- KMT2A | c.5423G>A p.R1808Q | Missense Mutation (SNP) | VAF 64/145 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs782730461, COSV100628245, COSV63288810; called by muse, mutect2, varscan2
- KPNA5 | c.841T>G p.Y281D | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100706127; called by muse, mutect2, varscan2
- MACF1 | c.12165A>T p.Q4055H (on ENST00000372915; = p.Q1988H on NM_012090.5) | Missense Mutation (SNP) | VAF 136/290 reads (47%) | catalogued as COSV99242253; called by muse, mutect2, varscan2
- MAGOHB | c.197T>G p.I66S | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100296236; called by muse, mutect2, varscan2
- NCOA1 | c.265A>T p.T89S | Missense Mutation (SNP) | VAF 64/161 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV99945455; called by muse, mutect2, varscan2
- NENF | c.335A>G p.H112R | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.223); catalogued as COSV65340938; called by muse, mutect2, varscan2
- NIPBL | c.6877A>G p.T2293A | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT tolerated (0.47); PolyPhen benign (0.173); catalogued as COSV99239444; called by muse, mutect2, varscan2
- NRAS | c.495G>T p.Q165H | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV101054558; called by muse, mutect2, varscan2
- NT5M | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 53/91 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV101198557; called by muse, mutect2, varscan2
- OPLAH | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.544); catalogued as rs781965027, COSV70678846; called by muse, mutect2
- PAK1 | c.68T>C p.M23T | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0.129); catalogued as COSV99583112; called by muse, mutect2, varscan2
- PARD3B | c.2126A>G p.K709R | Missense Mutation (SNP) | VAF 123/247 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as COSV100592528; called by muse, mutect2, varscan2
- PAX7 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 80/183 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV64750249; called by muse, mutect2, varscan2
- PCDH10 | c.1201G>T p.V401L | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.523); catalogued as rs1311321734, COSV99993160; called by muse, mutect2, varscan2
- PCDHGC3 | c.1363C>T p.P455S | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99338731; called by muse, mutect2
- PCLO | c.7814C>T p.P2605L | Missense Mutation (SNP) | VAF 104/157 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs763633017, COSV100428758; called by muse, mutect2, varscan2
- PER2 | c.2599G>A p.A867T | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV99611537; called by muse, mutect2
- PHRF1 | c.956G>A p.G319D | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99199650; called by muse, mutect2, varscan2
- PLEKHA6 | c.155T>C p.M52T | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV99691702; called by muse, mutect2, varscan2
- PLEKHG4B | c.2165A>T p.K722I (on ENST00000283426; = p.K1078I on NM_052909.5) | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV99359933; called by muse, mutect2, varscan2
- PLEKHG4B | c.2166A>T p.K722N (on ENST00000283426; = p.K1078N on NM_052909.5) | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV99359934; called by muse, mutect2, varscan2
- PRPF18 | c.800A>G p.D267G | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV100186999; called by muse, mutect2, varscan2
- PTPRR | c.627G>T p.E209D | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.675); catalogued as COSV99316618; called by muse, mutect2, varscan2
- RAB3GAP2 | c.506C>G p.T169S | Missense Mutation (SNP) | VAF 88/212 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs140312751, COSV99424509; called by muse, mutect2, varscan2
- RABEP1 | c.400C>T p.L134F | Missense Mutation (SNP) | VAF 90/160 reads (56%) | SIFT tolerated (0.72); PolyPhen benign (0.105); catalogued as COSV99336392; called by muse, mutect2, varscan2
- RLF | c.4182G>C p.E1394D | Missense Mutation (SNP) | VAF 70/149 reads (47%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV101035158; called by muse, mutect2, varscan2
- SIM2 | c.337G>T p.G113C | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99292983; called by muse, mutect2, varscan2
- SLC16A12 | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100370077; called by muse, mutect2, varscan2
- SLC36A2 | c.104C>G p.S35C | Missense Mutation (SNP) | VAF 62/142 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.502); catalogued as COSV100078985; called by muse, mutect2
- SLFN5 | c.1055C>A p.S352* | Nonsense Mutation (SNP) | VAF 101/158 reads (64%) | catalogued as COSV100249558; called by muse, mutect2, varscan2
- SNX9 | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.082); catalogued as rs1335131096, COSV101093882; called by muse, mutect2, varscan2
- SPATA7 | c.1480C>A p.P494T | Missense Mutation (SNP) | VAF 69/176 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99247806; called by muse, mutect2, varscan2
- SREBF2 | c.2206G>T p.A736S | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT tolerated (0.38); PolyPhen benign (0.077); catalogued as COSV63330939; called by muse, mutect2, varscan2
- TBC1D16 | c.1274G>A p.G425D | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1301737067, COSV100187802; called by muse, mutect2, varscan2
- TBC1D23 | c.1642G>A p.V548I (on ENST00000394144 / NM_001199198.3; = p.V533I on NM_018309.5) | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.571); catalogued as rs1363145475, COSV61368797; called by muse, mutect2, varscan2
- TMEM270 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV100260305; called by muse, mutect2, varscan2
- TRIM33 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); catalogued as COSV100635120; called by muse, mutect2
- TRIM33 | c.788C>A p.S263* | Nonsense Mutation (SNP) | VAF 44/123 reads (36%) | catalogued as COSV100635122; called by muse, mutect2
- TSC1 | c.757C>A p.H253N | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV100051352; called by muse, mutect2, varscan2
- TTC39A | c.301G>T p.V101L | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99396457; called by muse, mutect2, varscan2
- TTN | c.93784C>G p.P31262A (on ENST00000591111; = p.P23838A on NM_003319.4) | Missense Mutation (SNP) | VAF 40/93 reads (43%) | PolyPhen possibly damaging (0.701); catalogued as COSV100599775; called by muse, mutect2, varscan2
- TUB | c.1322T>C p.L441P (on ENST00000299506 / NM_177972.3; = p.L496P on NM_003320.4) | Missense Mutation (SNP) | VAF 36/63 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100210075; called by muse, mutect2, varscan2
- TXNDC16 | c.2467A>T p.K823* | Nonsense Mutation (SNP) | VAF 26/54 reads (48%) | catalogued as COSV99908950; called by muse, mutect2, varscan2
- UGT1A5 | c.797C>G p.P266R | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100529892; called by muse, mutect2, varscan2
- USO1 | c.2745T>A p.D915E | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV99362621; called by muse, mutect2, varscan2
- USP25 | c.613A>G p.N205D | Missense Mutation (SNP) | VAF 63/157 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs762491114, COSV99583332; called by muse, mutect2, varscan2
- VWA7 | c.99C>G p.I33M | Missense Mutation (SNP) | VAF 43/76 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as rs1212482242, COSV100791788; called by muse, mutect2, varscan2
- WDR17 | c.3666A>G p.R1222= | Splice Region (SNP) | VAF 38/95 reads (40%) | catalogued as rs995441678, COSV99707044; called by muse, mutect2, varscan2
- ZNF16 | c.2016G>T p.L672F | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs1235324181, COSV99429476; called by muse, mutect2, varscan2
- ZNF491 | c.414del p.A139Pfs*118 | Frame Shift Del (DEL) | VAF 33/89 reads (37%) | catalogued as COSV60056860; called by mutect2, pindel, varscan2
- ZNF552 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV101197510, COSV66971441; called by muse, mutect2, varscan2
- ADAMTS17 | c.34del p.L12Cfs*151 | Frame Shift Del (DEL) | VAF 19/74 reads (26%) | called by mutect2, pindel, varscan2
- ALG2 | c.987dup p.V330Cfs*16 | Frame Shift Ins (INS) | VAF 59/151 reads (39%) | called by mutect2, pindel, varscan2
- ANKRD30A | c.3989dup p.N1330Kfs*13 (on ENST00000611781; = p.N1274Kfs*13 on NM_052997.2) | Frame Shift Ins (INS) | VAF 85/213 reads (40%) | called by mutect2, pindel, varscan2
- APAF1 | c.2972del p.V991Efs*57 (on ENST00000551964 / NM_181861.2; = p.V937Efs*57 on NM_001160.3) | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | called by mutect2, pindel, varscan2
- BRCA1 | c.3700del p.V1234* | Frame Shift Del (DEL) | VAF 70/151 reads (46%) | called by mutect2, pindel, varscan2
- C11orf80 | c.1709dup p.R571Afs*13 | Frame Shift Ins (INS) | VAF 18/44 reads (41%) | called by mutect2, pindel
- DACH2 | c.719del p.N240Mfs*48 | Frame Shift Del (DEL) | VAF 93/244 reads (38%) | called by mutect2, pindel, varscan2
- FOXN1 | c.1343_1344del p.P448Lfs*32 | Frame Shift Del (DEL) | VAF 38/187 reads (20%) | called by mutect2, pindel, varscan2
- GLMN | c.1202dup p.Y401* | Nonsense Mutation (INS) | VAF 68/201 reads (34%) | called by mutect2, pindel, varscan2
- ITGAX | c.3238_3240del p.S1080del | In Frame Del (DEL) | VAF 32/90 reads (36%) | called by mutect2, pindel, varscan2
- LIMA1 | c.1791dup p.Q598Sfs*26 | Frame Shift Ins (INS) | VAF 22/54 reads (41%) | called by mutect2, pindel, varscan2
- NOVA2 | c.892dup p.L298Pfs*106 | Frame Shift Ins (INS) | VAF 7/17 reads (41%) | called by mutect2, pindel, varscan2
- OR52M1 | c.217dup p.L73Pfs*21 | Frame Shift Ins (INS) | VAF 36/104 reads (35%) | called by mutect2, pindel, varscan2
- PLCD1 | c.469del p.D157Tfs*4 | Frame Shift Del (DEL) | VAF 43/116 reads (37%) | called by mutect2, pindel, varscan2
- PREX1 | c.3515_3529delinsG p.E1172Gfs*13 | Frame Shift Del (DEL) | VAF 29/73 reads (40%) | called by pindel, varscan2*
- RABGGTB | c.585_586dup p.C196Ffs*16 | Frame Shift Ins (INS) | VAF 13/50 reads (26%) | called by mutect2, pindel, varscan2
- ACSL5 | c.441C>T p.I147= (on ENST00000354273; = p.I203= on NM_016234.3) | Silent (SNP) | VAF 48/93 reads (52%) | catalogued as COSV100634521; called by muse, mutect2, varscan2
- ALDH3A2 | c.240T>C p.T80= | Silent (SNP) | VAF 50/120 reads (42%) | catalogued as COSV99449683; called by muse, varscan2
- CCDC136 | c.480C>T p.S160= | Silent (SNP) | VAF 40/110 reads (36%) | catalogued as rs776548870, COSV52798676; called by muse, mutect2, varscan2
- DGLUCY | c.600G>A p.L200= | Silent (SNP) | VAF 32/75 reads (43%) | catalogued as COSV99824117; called by muse, mutect2, varscan2
- DTX1 | c.1104G>T p.V368= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as COSV99986253; called by muse, mutect2, varscan2
- EPRS1 | c.2841A>T p.G947= | Silent (SNP) | VAF 52/116 reads (45%) | catalogued as COSV100859331; called by muse, mutect2, varscan2
- EPS8L2 | c.621C>A p.P207= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV100585395; called by muse, mutect2, varscan2
- FAM135B | c.1365T>C p.S455= | Silent (SNP) | VAF 72/183 reads (39%) | catalogued as COSV99420581; called by muse, mutect2, varscan2
- FERMT3 | c.219G>A p.L73= | Silent (SNP) | VAF 52/131 reads (40%) | catalogued as COSV99656380; called by muse, mutect2, varscan2
- FMR1 | c.720T>C p.N240= | Silent (SNP) | VAF 132/309 reads (43%) | catalogued as COSV99503058; called by muse, mutect2, varscan2
- GPN2 | c.294G>A p.K98= | Silent (SNP) | VAF 47/94 reads (50%) | catalogued as rs769087017, COSV100658716; called by muse, mutect2, varscan2
- IKBKG | c.786T>C p.D262= | Silent (SNP) | VAF 49/252 reads (19%) | called by muse, mutect2, varscan2
- INTS2 | c.2541G>A p.K847= | Silent (SNP) | VAF 35/117 reads (30%) | catalogued as COSV52150837, COSV99247887; called by muse, mutect2, varscan2
- LPIN3 | c.825T>C p.P275= | Silent (SNP) | VAF 47/84 reads (56%) | catalogued as COSV100952928; called by muse, mutect2, varscan2
- LSMEM2 | c.267C>T p.C89= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as COSV100269324; called by muse, mutect2, varscan2
- MAGEF1 | c.690T>G p.P230= | Silent (SNP) | VAF 31/66 reads (47%) | catalogued as COSV100510921; called by muse, mutect2, varscan2
- MAST4 | c.6897G>A p.E2299= (on ENST00000403625 / NM_001164664.2; = p.E2110= on NM_015183.3) | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as rs781119007, COSV99843271; called by muse, mutect2, varscan2
- MYBPC3 | c.2937G>A p.L979= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV99920024; called by muse, mutect2, varscan2
- OGA | c.66C>T p.A22= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV100761682; called by muse, mutect2, varscan2
- OR51D1 | c.396T>C p.A132= | Silent (SNP) | VAF 29/87 reads (33%) | catalogued as COSV100712353; called by muse, mutect2, varscan2
- PCARE | c.1737C>T p.S579= | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as COSV100527389; called by muse, mutect2, varscan2
- PPT2 | c.195G>T p.G65= | Silent (SNP) | VAF 45/87 reads (52%) | catalogued as COSV99278272; called by muse, mutect2, varscan2
- RNF20 | c.213A>G p.E71= | Silent (SNP) | VAF 57/100 reads (57%) | catalogued as rs150763272; called by muse, mutect2, varscan2
- SNX27 | c.1575A>G p.K525= | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as COSV100918985; called by muse, mutect2, varscan2
- SP3 | c.1107G>A p.Q369= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as COSV100021678; called by muse, mutect2, varscan2
- SVIL | c.5343T>C p.Y1781= (on ENST00000355867 / NM_021738.3; = p.Y1355= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/91 reads (46%) | catalogued as rs773565742, COSV100881069; called by muse, mutect2, varscan2
- TLX1 | c.684G>A p.S228= | Silent (SNP) | VAF 43/100 reads (43%) | catalogued as COSV100930035; called by muse, mutect2, varscan2
- TNFRSF11A | c.1731C>T p.R577= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV99500040; called by muse, mutect2, varscan2
- TNFRSF8 | c.588G>T p.G196= | Silent (SNP) | VAF 55/116 reads (47%) | catalogued as COSV99821189; called by muse, mutect2, varscan2
- TRERF1 | c.3003G>T p.P1001= | Silent (SNP) | VAF 32/77 reads (42%) | catalogued as COSV100550153; called by muse, mutect2, varscan2
- TTN | c.10260T>C p.N3420= (on ENST00000591111; = p.N3374= on NM_003319.4) | Silent (SNP) | VAF 33/94 reads (35%) | catalogued as COSV100599777; called by muse, mutect2, varscan2
- UIMC1 | c.945T>A p.L315= | Silent (SNP) | VAF 36/88 reads (41%) | catalogued as COSV101022070; called by muse, mutect2, varscan2
- USF3 | c.4053C>T p.P1351= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as rs752645271, COSV100324881; called by muse, mutect2, varscan2
- VWF | c.5682C>G p.T1894= | Silent (SNP) | VAF 105/209 reads (50%) | catalogued as COSV99778368; called by muse, mutect2, varscan2
- YLPM1 | c.3567T>C p.P1189= | Silent (SNP) | VAF 30/59 reads (51%) | catalogued as COSV99458894; called by muse, mutect2, varscan2
- ZNF687 | c.2049G>T p.R683= | Silent (SNP) | VAF 24/45 reads (53%) | catalogued as COSV99649398, COSV99649498; called by muse, mutect2, varscan2
- ANKRD13D | c.*340G>A | 3'UTR (SNP) | VAF 25/90 reads (28%) | catalogued as rs1476631894, COSV100398357, COSV57750854; called by muse, mutect2, varscan2
- DNA2 | c.-81T>C | 5'UTR (SNP) | VAF 46/105 reads (44%) | catalogued as COSV100622433; called by muse, mutect2, varscan2
- MASP2 | c.544+463del | Intron (DEL) | VAF 51/126 reads (40%) | called by mutect2, pindel, varscan2
- S1PR3 | c.-204A>C | 5'UTR (SNP) | VAF 10/17 reads (59%) | catalogued as COSV100560804; called by muse, mutect2, varscan2
